Somatic mutation profile of tumor specimen TCGA-WX-AA46-01A (aliquot TCGA-WX-AA46-01A-11D-A38X-10) from TCGA case TCGA-WX-AA46, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 62.0 years (22,639 days).
Specimen TCGA-WX-AA46-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16c756ee-4ebb-4868-b1c5-dfc54c7fafe6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WX-AA46-10A (Blood Derived Normal), aliquot TCGA-WX-AA46-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/448bb1e4-87c2-4145-8693-fa99a512e22e

The open-access MAF lists 61 somatic variants for this specimen: 50 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 42, Silent 11, Nonsense Mutation 5, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM3 | c.1034G>A p.G345D | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV100447936; called by muse, mutect2
- AKR1B1 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 41/104 reads (39%) | catalogued as COSV53647811; called by muse, mutect2, varscan2
- ALPG | c.1419G>T p.E473D | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV99779107; called by muse, mutect2
- AMBN | c.442A>G p.I148V | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV100534225; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.5227A>T p.I1743F | Missense Mutation (SNP) | VAF 10/346 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99781752; called by muse, mutect2
- BRPF1 | c.1308C>G p.F436L | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV100121043; called by muse, mutect2
- CARNS1 | c.2082G>A p.M694I | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs781669252, COSV57049850; called by muse, mutect2, varscan2
- CLTC | c.423G>A p.M141I | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99291532; called by muse, mutect2
- CNTN2 | c.2070T>G p.I690M | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV100084548; called by muse, mutect2
- COL11A1 | c.2350G>T p.G784C | Missense Mutation (SNP) | VAF 158/545 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100614470; called by muse, varscan2
- COL4A2 | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 14/196 reads (7%) | catalogued as COSV100847068; called by muse, mutect2
- CPSF7 | c.931A>G p.M311V (on ENST00000394888 / NM_001136040.4; = p.M354V on NM_024811.4) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs143271041; called by muse, mutect2, varscan2
- CREB5 | c.188C>T p.T63M (on ENST00000357727 / NM_182898.4; = p.T56M on NM_004904.3) | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762102181, COSV63220795; called by muse, mutect2
- CS | c.1259A>G p.Y420C | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100369882; called by muse, mutect2, varscan2
- DNAH9 | c.818C>G p.T273R | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV52343687; called by muse, mutect2
- DPF1 | c.147C>G p.H49Q | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.241); catalogued as COSV100831393; called by muse, mutect2, varscan2
- EID2B | c.308G>T p.S103I | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV100410966; called by muse, mutect2
- ELAC1 | c.518T>G p.F173C | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53996180; called by muse, mutect2
- FAM135B | c.4103A>C p.H1368P | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99417316; called by muse, mutect2
- GPR158 | c.3520T>A p.W1174R | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100892618; called by muse, mutect2, varscan2
- IFI44L | c.1165A>G p.K389E | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV100654831; called by muse, mutect2
- IGHG1 | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1443357057; called by muse, mutect2, varscan2
- KIFBP | c.1455G>C p.M485I | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV100741341; called by muse, mutect2
- LCOR | c.1742A>G p.D581G | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV99616434; called by muse, mutect2
- LRRC43 | c.1337G>A p.C446Y | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as COSV100336468; called by muse, mutect2, varscan2
- MED23 | c.593A>G p.H198R | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs759582160, COSV100644671; called by muse, mutect2, varscan2
- OR11H6 | c.594C>A p.D198E | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100209678; called by muse, mutect2, varscan2
- PANK2 | c.1508C>T p.S503L (on ENST00000316562 / NM_153638.3; = p.S212L on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100262012; called by muse, mutect2, varscan2
- PLK3 | c.435+1G>T p.X145_splice | Splice Site (SNP) | VAF 5/111 reads (5%) | catalogued as COSV100220970; called by muse, mutect2
- POSTN | c.1808T>C p.L603P | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.723); catalogued as COSV101123201; called by muse, mutect2, varscan2
- PRAME | c.392A>G p.D131G | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV101286993; called by muse, mutect2, varscan2
- PRKDC | c.5683A>G p.K1895E | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV100037927; called by muse, mutect2
- PSMC6 | c.163G>T p.E55* (on ENST00000612399; = p.E41* on NM_002806.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 40/127 reads (31%) | catalogued as COSV101471171, COSV101471172; called by muse, mutect2, varscan2
- SERPINB3 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.497); catalogued as rs377088096; called by muse, mutect2, varscan2
- SNX19 | c.2533C>T p.Q845* | Nonsense Mutation (SNP) | VAF 5/127 reads (4%) | catalogued as COSV99772689; called by muse, mutect2
- SNX19 | c.2532G>T p.M844I | Missense Mutation (SNP) | VAF 5/123 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99772691; called by muse, mutect2
- SPART | c.811-2A>G p.X271_splice | Splice Site (SNP) | VAF 28/88 reads (32%) | catalogued as COSV100768511; called by muse, mutect2, varscan2
- SYN3 | c.1632C>A p.N544K | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100248073; called by muse, mutect2
- TNFRSF10A | c.679A>G p.I227V | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.842); catalogued as COSV99645998; called by muse, mutect2, varscan2
- TTN | c.72380T>G p.L24127R (on ENST00000591111; = p.L16703R on NM_003319.4) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | PolyPhen possibly damaging (0.563); catalogued as COSV100589432; called by muse, mutect2
- TXNDC5 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866550615, COSV101124300; called by muse, mutect2, varscan2
- VAV3 | c.2273T>C p.L758S | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100578931, COSV58392712; called by muse, mutect2, varscan2
- VDAC1 | c.334G>C p.A112P | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV99527088; called by muse, mutect2, varscan2
- WDR37 | c.14G>C p.S5T | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV99579113; called by muse, mutect2
- WNT1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.041); catalogued as COSV99525184; called by muse, mutect2, varscan2
- WRN | c.2409G>T p.R803S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53296064, COSV99988057; called by muse, mutect2, varscan2
- XPO5 | c.2479C>T p.P827S | Missense Mutation (SNP) | VAF 7/177 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV99540217, COSV99540511; called by muse, mutect2
- ZNF318 | c.6617G>A p.G2206E | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.976); catalogued as rs1305153427, COSV100545868; called by muse, mutect2
- ZNF407 | c.1781C>G p.S594* | Nonsense Mutation (SNP) | VAF 7/116 reads (6%) | catalogued as COSV99047293, COSV99994583; called by muse, mutect2
- PPP2R5C | c.647_648del p.E216Afs*3 | Frame Shift Del (DEL) | VAF 21/114 reads (18%) | called by pindel, varscan2
- AMD1 | c.6A>G p.E2= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100924442; called by muse, mutect2, varscan2
- AP1B1 | c.2427G>C p.L809= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV100434277; called by muse, mutect2, varscan2
- COL16A1 | c.1374T>C p.P458= | Silent (SNP) | VAF 46/134 reads (34%) | catalogued as rs1417261811, COSV99593284; called by muse, mutect2, varscan2
- DAOA | c.198G>A p.E66= | Silent (SNP) | VAF 39/163 reads (24%) | catalogued as COSV100298612; called by muse, mutect2, varscan2
- KAT6A | c.1515A>G p.Q505= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV99704167; called by muse, mutect2, varscan2
- MT1H | c.185G>A p.*62= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100189875; called by muse, mutect2, varscan2
- SEPTIN4 | c.96A>T p.G32= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100421830; called by muse, mutect2, varscan2
- TCFL5 | c.762A>G p.Q254= | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as COSV99415441; called by muse, mutect2, varscan2
- TRA2B | c.162T>A p.S54= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99373141; called by muse, mutect2, varscan2
- TYR | c.849C>T p.N283= | Silent (SNP) | VAF 51/155 reads (33%) | catalogued as rs1422178272, COSV99632667; called by muse, mutect2, varscan2
- WDR26 | c.1869A>G p.V623= (on ENST00000414423 / NM_001379403.1; = p.V523= on NM_025160.7) | Silent (SNP) | VAF 13/499 reads (3%) | catalogued as COSV99690773; called by muse, mutect2
